Somatic mutation profile of tumor specimen 42cc89e1-a896-4f57-b8d9-e7fe56 (aliquot 42cc89e1-a896-4f57-b8d9-e7fe56_D6) from CPTAC case 01BR015, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 35.0 years (12,774 days).
Specimen 42cc89e1-a896-4f57-b8d9-e7fe56: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e2277749-c3be-4e19-8c33-8e3e4fdeb78b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen f99563c8-f45c-4508-a41c-620e7c (Blood Derived Normal), aliquot f99563c8-f45c-4508-a41c-620e7c_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fa5d08a7-1880-4361-8f1e-09b0128abce5

The open-access MAF lists 61 somatic variants for this specimen: 34 protein-altering or splice-affecting, 24 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 24, Nonsense Mutation 1, In Frame Del 1, Intron 1, Splice Region 1, 3'Flank 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1256_1261del p.H419_C420del | In Frame Del (DEL) | VAF 19/33 reads (58%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- TP53 | c.832C>A p.P278T | Missense Mutation (SNP) | VAF 174/339 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs17849781, CM011015, CM052927, CM120850, CX0910928, COSV52668132, COSV52679740, COSV52684662, COSV52950563; ClinVar: likely pathogenic / drug response; called by mutect2, varscan2
- AHNAK | c.14602G>A p.D4868N | Missense Mutation (SNP) | VAF 37/147 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.327); catalogued as rs1275466601; called by muse, mutect2, varscan2
- AHNAK2 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 36/193 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100315892; called by muse, mutect2, varscan2
- ANKRD36 | c.3189G>C p.L1063F | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT tolerated, low confidence (0.23); PolyPhen probably damaging (0.991); catalogued as COSV101347496; called by muse, mutect2, varscan2
- CCDC93 | c.949C>G p.R317G | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV60119161, COSV60122319; called by muse, mutect2, varscan2
- CCNO | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs771896675; called by muse, mutect2, varscan2
- COBL | c.136G>A p.G46R | Missense Mutation (SNP) | VAF 25/238 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.129); catalogued as rs566661748, COSV54343208, COSV99474100; called by muse, mutect2, varscan2
- DNAH12 | c.5827C>T p.R1943C (on ENST00000351747; = p.R1962C on NM_001366028.2) | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs144837963; called by muse, mutect2, varscan2
- DNAH17 | c.5554G>A p.G1852S | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs370592347; called by muse, mutect2, varscan2
- LDLRAD3 | c.779C>T p.S260F | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as COSV100215451; called by muse, mutect2, varscan2
- MTCH2 | c.445A>G p.M149V | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as rs761783479; called by muse, mutect2, varscan2
- OR14I1 | c.802C>T p.Q268* | Nonsense Mutation (SNP) | VAF 16/196 reads (8%) | catalogued as COSV61201111; called by muse, mutect2
- PTPRD | c.2920C>T p.P974S | Missense Mutation (SNP) | VAF 39/233 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.105); catalogued as rs765439647, COSV61961220; called by muse, mutect2, varscan2
- RARS2 | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 61/360 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.025); catalogued as rs747644029; called by muse, mutect2, varscan2
- RBM17 | c.673G>A p.G225R | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as COSV101159210; called by muse, mutect2
- SIMC1 | c.2347G>A p.V783I (on ENST00000443967 / NM_001308196.1; = p.V368I on NM_198567.5) | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.747); catalogued as rs374421813; called by muse, mutect2, varscan2
- TOP2B | c.3713A>G p.Y1238C (on ENST00000264331 / NM_001330700.2; = p.Y1233C on NM_001068.3) | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs765906123, COSV51968393; called by muse, mutect2, varscan2
- TUBA3C | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 33/187 reads (18%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.037); catalogued as rs778228340, COSV67139976; called by muse, mutect2, varscan2
- XPNPEP2 | c.851C>T p.S284F | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.112); catalogued as rs767940039, COSV64369444; called by muse, mutect2, varscan2
- ABR | c.1642G>A p.E548K (on ENST00000302538 / NM_021962.5; = p.E511K on NM_001092.5) | Missense Mutation (SNP) | VAF 10/163 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.794); called by muse, mutect2
- BPI | c.1420C>T p.H474Y (on ENST00000262865; = p.H470Y on NM_001725.3) | Missense Mutation (SNP) | VAF 32/172 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DZIP1L | c.2035G>A p.E679K | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- EPB41L1 | c.1124G>A p.R375Q | Missense Mutation (SNP) | VAF 50/299 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LAMA3 | c.5165A>G p.Y1722C (on ENST00000313654 / NM_198129.4; = p.Y113C on NM_000227.6) | Missense Mutation (SNP) | VAF 34/290 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- LDB1 | c.858G>T p.A286= (on ENST00000425280 / NM_001321612.2; = p.A250= on NM_003893.5) | Splice Region (SNP) | VAF 20/158 reads (13%) | called by mutect2, varscan2
- MAP2K4 | c.777_778del p.K260Dfs*7 | Frame Shift Del (DEL) | VAF 47/103 reads (46%) | called by mutect2, pindel, varscan2
- PCMTD1 | c.74G>C p.R25P | Missense Mutation (SNP) | VAF 55/252 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- PPP2R1A | c.595G>C p.D199H | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SDHB | c.533A>G p.E178G | Missense Mutation (SNP) | VAF 63/267 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- STAM | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TLE4 | c.1946G>A p.R649H | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- TMEM70 | c.752G>A p.S251N | Missense Mutation (SNP) | VAF 16/436 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2
- TRAPPC6B | c.94T>C p.C32R | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.43); PolyPhen benign (0.326); called by muse, varscan2
- ANKRD12 | c.1209G>A p.E403= | Silent (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2
- ARHGAP26 | c.2277G>A p.R759= | Silent (SNP) | VAF 22/95 reads (23%) | called by muse, mutect2, varscan2
- BRD1 | c.741G>T p.G247= | Silent (SNP) | VAF 42/162 reads (26%) | called by mutect2, varscan2
- C2CD3 | c.933C>T p.L311= | Silent (SNP) | VAF 19/161 reads (12%) | catalogued as COSV100486944; called by muse, mutect2, varscan2
- CDC42BPG | c.3933C>T p.H1311= | Silent (SNP) | VAF 31/186 reads (17%) | catalogued as rs760868480, COSV61348195; called by muse, mutect2, varscan2
- HELB | c.2796C>A p.L932= | Silent (SNP) | VAF 36/304 reads (12%) | called by mutect2, varscan2
- HSF4 | c.630C>A p.S210= | Silent (SNP) | VAF 46/362 reads (13%) | catalogued as COSV50459315; called by muse, mutect2, varscan2
- IDUA | c.699G>C p.L233= | Silent (SNP) | VAF 50/388 reads (13%) | called by muse, mutect2, varscan2
- LUZP1 | c.2154G>C p.V718= | Silent (SNP) | VAF 7/189 reads (4%) | called by muse, mutect2
- LY6G6E | c.57C>T p.L19= | Silent (SNP) | VAF 19/124 reads (15%) | called by muse, mutect2, varscan2
- MDM1 | c.1086G>A p.Q362= | Silent (SNP) | VAF 22/108 reads (20%) | called by muse, mutect2, varscan2
- MYO1F | c.2004G>A p.Q668= | Silent (SNP) | VAF 56/272 reads (21%) | catalogued as COSV100596331; called by muse, mutect2, varscan2
- OR5D18 | c.537C>T p.F179= | Silent (SNP) | VAF 121/501 reads (24%) | catalogued as COSV61736345; called by muse, mutect2, varscan2
- PPP6C | c.681C>T p.I227= | Silent (SNP) | VAF 10/186 reads (5%) | catalogued as COSV65209702; called by muse, mutect2
- SHC2 | c.1188C>T p.D396= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs367845097; called by muse, mutect2
- SIRPB1 | c.99A>G p.L33= | Silent (SNP) | VAF 42/208 reads (20%) | catalogued as rs199531018; called by muse, mutect2
- THPO | c.1179C>T p.L393= (on ENST00000649095 / NM_001290003.1; = p.L253= on NM_000460.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 144/357 reads (40%) | called by muse, mutect2, varscan2
- TMPRSS3 | c.387C>T p.C129= | Silent (SNP) | VAF 242/682 reads (35%) | called by muse, mutect2, varscan2
- TNR | c.228C>T p.D76= | Silent (SNP) | VAF 147/452 reads (33%) | called by muse, mutect2, varscan2
- TTN | c.92400C>T p.D30800= (on ENST00000591111; = p.D23376= on NM_003319.4) | Silent (SNP) | VAF 30/103 reads (29%) | catalogued as rs749961745; ClinVar: likely benign; called by muse, mutect2, varscan2
- UNC79 | c.5229G>A p.L1743= (on ENST00000393151 / NM_001346218.2; = p.L1566= on NM_020818.5) | Silent (SNP) | VAF 35/174 reads (20%) | catalogued as rs201928468; called by muse, mutect2, varscan2
- VWCE | c.2067C>T p.Y689= | Silent (SNP) | VAF 28/144 reads (19%) | catalogued as rs773833904, COSV57112589, COSV57115227; called by muse, mutect2, varscan2
- ZNF618 | c.2310G>C p.L770= (on ENST00000374126 / NM_001318042.2; = p.L677= on NM_133374.2) | Silent (SNP) | VAF 16/271 reads (6%) | called by muse, mutect2
- ZNF667 | c.1236G>A p.K412= | Silent (SNP) | VAF 39/193 reads (20%) | catalogued as COSV99410095; called by muse, mutect2, varscan2
- BOD1P2 | n.120C>T | RNA (SNP) | VAF 18/108 reads (17%) | called by muse, mutect2, varscan2
- MIR6511B2 | chr16:15130234 C>T | 3'Flank (SNP) | VAF 173/760 reads (23%) | catalogued as rs879848396; called by muse, mutect2, varscan2
- TNIP3 | c.946+640T>C | Intron (SNP) | VAF 15/121 reads (12%) | called by muse, mutect2, varscan2
